Surgical pathology report (de-identified scan), TCGA case TCGA-A3-3328, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site International Genomics Consortium, specimen TCGA-A3-3328-01A (Primary Tumor).

[page 1 of 2]
Surgical Pathology

Histopathological Examination

Path#: [REDACTED]
Collected: [REDACTED]Pre-Op Diagnosis : Left Kidney Tumor
Order Physician : [REDACTED] MD
Specimens : Kidney, left pelvic kidney for [REDACTED] out at [REDACTED]
Frozen Diagnosis :

Report : GROSS EXAMINATION.
The specimen is received in a container labeled with the name of the patient and labeled as kidney, left pelvic kidney. Received fresh is a nephrectomy specimen including perinephric fat that measures en bloc 10 x 9.3 x 7.8cm. The 7.5 x 7.4 x 5.4cm kidney weighs approximately 140gm and has a posterior, 5.6 x 5.4 x 5.2 cm, hemorrhagic, circumscribed, tan yellow tumor mass near the superior pole. The cortex has a maximum thickness of 0.8 cm. The renal pyramids are blunted. The pelvis is focally hyperemic. The 2.3cm long ureter has maximum diameter of 0.5 cm. A possible fat replaced lymph node measures 1.6 cm. Sections are submitted in 8 blocks as follows: 1-4 tumor mass; 5-6 random kidney; 7-renal vessels and ureter; 8-possible lymph node. [REDACTED]

DIAGNOSIS BASED ON GROSS AND MICROSCOPIC EXAMINATION:

SPECIMEN TYPE: Radical nephrectomy
LATERALITY: Left
TUMOR SITE: Middle
FOCALITY: Unifocal
TUMOR SIZE: Greatest dimension: 5.6 cm
MACROSCOPIC EXTENT OF TUMOR: Tumor limited to kidney
HISTOLOGIC TYPE: Clear cell (conventional) renal carcinoma
HISTOLOGIC GRADE (FUHRMAN NUCLEAR GRADE): Grade 2
EXTENT OF INVASION
PRIMARY TUMOR (PT): pT1b: Tumor more than 4 cm but not more than 7 cm in greatest dimension, limited to the kidney
REGIONAL LYMPH NODES (PN): pN0: No regional lymph node metastasis.
Number examined: 1
Number involved: 0
DISTANT METASTASIS (PM): pMX: Cannot be assessed
MARGINS: Margins uninvolved by invasive carcinoma

THIS CONFIDENTIAL AND
FEDERAL AND STATEMENT/INFORMATION IS PROTECTED BY
REASONED DISCLOSURE, DISSEMINATION
IS PROHIBITED

[page 2 of 2]
ADRENAL GLAND: Not present
VENOUS (LARGE VESSEL) INVASION (V): Absent
LYMPHATIC (SMALL VESSEL) INVASION (L): Absent
ADDITIONAL PATHOLOGIC FINDINGS: None identified.
Intradepartmental consultation obtained.
[T-71000 M-83103 189.0 P3-44070]

COMMENT:

Findings discussed with [REDACTED] on [REDACTED]

[REDACTED] M.D., Pathology
[REDACTED]

Electronically Signed by:

[REDACTED] MD

[REDACTED]

THIS CONFIDENTIAL AND PRIVILEGED DOCUMENT/INFORMATION IS PROTECTED BY
FEDERAL AND STATE LAW. UNAUTHORIZED DISCLOSURE, DISSEMINATION
OR DUPLICATION IS PROHIBITED

Source: NCI Genomic Data Commons file 7f15ad0a-d8d6-490a-815b-832b4ce1a9f5 (TCGA-A3-3328.BE826B4D-E1F0-4170-8C62-66E6800AE852.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).